Gene-level copy-number profile of tumor specimen TCGA-DX-A7EL-01A from TCGA case TCGA-DX-A7EL, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 56.9 years (20,767 days).
Specimen TCGA-DX-A7EL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.b97dd03b-40e3-4a98-a56d-bbc8f7f03a4b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A7EL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/520bf68a-fda3-416d-8df8-61e502b6c995

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 88; copy number 1: 6,855; copy number 2: 46,710; copy number 3: 2,770; copy number 4: 2,883; copy number 5: 64; copy number 6: 443.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A7EL-01A-12D-A40C-01): tumor purity 0.72, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 88 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:20,806,292–21,345,572, 10 genes (within-gene range 0–1): EIF4G3, RNU7-200P, MIR1256, RPS15AP6, AL627311.1, HSPE1P27, AL031005.2, ECE1, AL031005.1, ECE1-AS1.
- chr2:39,436,530–41,157,555, 11 genes: MAP4K3-DT, TMEM178A, THUMPD2, SLC8A1-AS1, AC007253.1, SLC8A1, AC007877.1, AC007317.1, AC007317.2, LINC01794, HNRNPA1P57.
- chr13:48,232,612–51,080,862, 65 genes (broad region; genes not listed).
- chr13:96,883,842–96,885,821, 1 gene: HSP90AB6P.
- chr13:103,043,998–103,066,417, 1 gene: SLC10A2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 507 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:128,292,751–159,777,828, 443 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr14:22,415,362–22,536,204, 64 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,855. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
